Somatic mutation profile of tumor specimen MMRF_2197_1_BM_CD138pos (aliquot MMRF_2197_1_BM_CD138pos_T1_KHS5U_L08823) from MMRF case MMRF_2197, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.0 years (29,953 days).
Specimen MMRF_2197_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0b85d37-ad52-4b74-b64b-92cb8151b5b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2197_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2197_1_PB_WBC_C3_KHS5U_L08790; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9e5105d-b9bc-44a9-a6a2-83e6712bca0a

The open-access MAF lists 193 somatic variants for this specimen: 82 protein-altering or splice-affecting, 15 silent, 96 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, 3'UTR 53, Intron 21, Silent 15, 5'UTR 9, 5'Flank 6, 3'Flank 5, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL121899.2 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199889633; called by muse, mutect2, varscan2
- ALDH4A1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756567062; called by muse, mutect2, varscan2
- ATM | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as CD992489; called by muse, mutect2, varscan2
- BMP5 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376923719; called by muse, mutect2, varscan2
- CABP2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1195009247; called by muse, mutect2, varscan2
- CCDC88C | c.2534G>T p.W845L | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.621); catalogued as rs1202419452; called by muse, mutect2, varscan2
- CCNP | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs1432248934, COSV55687452; called by muse, mutect2, varscan2
- CDC42BPG | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs756877252; called by muse, mutect2, varscan2
- CIDEA | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.862); catalogued as rs751972278, COSV57598855; called by muse, mutect2, varscan2
- COL4A1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65427455; called by muse, mutect2, varscan2
- GPAT3 | c.1147T>C p.F383L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1223090511; called by muse, varscan2
- HECW1 | c.2232C>A p.S744R | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as COSV101224118; called by muse, mutect2, varscan2
- HECW2 | c.4354G>C p.G1452R | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647747; called by muse, mutect2, varscan2
- HERC1 | c.7511G>A p.R2504K | Missense Mutation (SNP) | VAF 93/514 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV101496505; called by muse, mutect2, varscan2
- IGKV4-1 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs541963022; called by muse, mutect2, varscan2
- IGKV4-1 | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.619); catalogued as rs572656022; called by muse, mutect2, varscan2
- IGLV3-1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs560070339; called by muse, mutect2, varscan2
- ITGB6 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs770284828; called by muse, mutect2, varscan2
- LAMA4 | c.944A>G p.N315S (on ENST00000230538 / NM_001105206.3; = p.N308S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1029188462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBNL3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV100898504; called by muse, mutect2, varscan2
- OR8I2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 89/373 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs957050386, COSV56170047; called by muse, mutect2, varscan2
- PIWIL4 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs542040289; called by muse, mutect2, varscan2
- SBNO1 | c.2183G>A p.S728N (on ENST00000420886; = p.S727N on NM_018183.5) | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs143322432; called by muse, mutect2, varscan2
- SGO1 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs769229657; called by muse, mutect2
- SNAPC2 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1176024079; called by muse, mutect2, varscan2
- STOML1 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs778449008; called by muse, mutect2, varscan2
- TENT5C | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs754072349, COSV65616259; called by muse, mutect2, varscan2
- USP5 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1425977684; called by muse, mutect2, varscan2
- ADAM11 | c.1318A>T p.K440* | Nonsense Mutation (SNP) | VAF 38/169 reads (22%) | called by muse, mutect2, varscan2
- ADAM11 | c.1433C>A p.T478N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AIM2 | c.731G>C p.R244T | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); called by muse, mutect2
- ANTXRL | c.1748G>C p.C583S | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.946); called by muse, mutect2
- ARHGAP21 | c.5023A>C p.S1675R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ARHGAP31 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ARID1A | c.1592dup p.A532Gfs*91 | Frame Shift Ins (INS) | VAF 59/219 reads (27%) | called by mutect2, pindel, varscan2
- BCCIP | c.180A>C p.E60D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BCCIP | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C3orf20 | c.-134A>G | Splice Region (SNP) | VAF 38/392 reads (10%) | called by muse, mutect2
- CCDC89 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEP192 | c.3606_3619del p.K1202Nfs*4 | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | called by mutect2, pindel, varscan2
- CNTN4 | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COPB2 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CPD | c.3661G>T p.D1221Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCDC2C | c.601C>G p.H201D | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- DCLK3 | c.1184_1185del p.K395Rfs*7 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | called by mutect2, pindel, varscan2
- DSP | c.5908G>T p.G1970W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF2AK1 | c.1531T>C p.S511P | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FABP3 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GHR | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HLCS | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPU | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- INSYN2A | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX3 | c.1385A>T p.D462V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- ITIH2 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNT1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- LAMA4 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MALRD1 | c.2186G>A p.G729E | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MAU2 | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- MTA2 | c.1524G>C p.K508N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MYO3A | c.3309del p.E1104Kfs*5 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- NTNG2 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR8J1 | c.470T>C p.I157T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2
- PHIP | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PTPRC | c.2145T>G p.G715= | Splice Region (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- RFTN1 | c.659G>T p.S220I | Missense Mutation (SNP) | VAF 94/189 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- RP1 | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- RPL13 | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SESN3 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SHROOM3 | c.2101G>T p.A701S | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.038); called by muse, mutect2
- SNRK | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2
- SPTBN2 | c.7088C>A p.A2363D | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TBCK | c.544G>A p.G182S (on ENST00000273980 / NM_001163436.4; = p.G119S on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TFAP2A | c.422C>T p.A141V (on ENST00000482890; = p.A133V on NM_001032280.3) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLR5 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- TRAF3 | c.1463G>A p.W488* | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- TROAP | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- VCP | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13C | c.5016C>G p.F1672L (on ENST00000644861 / NM_020821.3; = p.F1629L on NM_017684.5) | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2
- VRTN | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- XPOT | c.2135T>C p.I712T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2
- XRN1 | c.2806_2808del p.F936del | In Frame Del (DEL) | VAF 20/189 reads (11%) | called by mutect2, pindel
- ZFP14 | c.1382T>G p.F461C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRA1D | c.300C>T p.G100= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs1334576627; called by muse, mutect2, varscan2
- CDH12 | c.918C>T p.Y306= | Silent (SNP) | VAF 86/348 reads (25%) | called by muse, mutect2, varscan2
- FMN2 | c.2776C>T p.L926= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100147111; called by muse, mutect2
- GABRB2 | c.1179C>T p.F393= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV50926511, COSV50951184; called by muse, mutect2
- GLCCI1 | c.123C>T p.N41= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1324161383; called by muse, mutect2
- ITGB4 | c.3579G>A p.E1193= | Silent (SNP) | VAF 80/195 reads (41%) | called by muse, mutect2, varscan2
- KIAA1549L | c.3630C>T p.N1210= (on ENST00000321505; = p.N1507= on NM_012194.3) | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs575072624; called by muse, mutect2, varscan2
- N4BP1 | c.2079G>A p.R693= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- RABEP2 | c.195G>A p.E65= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV62868732; called by muse, mutect2
- ROBO2 | c.1476T>C p.S492= | Silent (SNP) | VAF 71/115 reads (62%) | called by muse, mutect2, varscan2
- SPDYE4 | c.105A>G p.P35= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- TLE1 | c.492T>G p.L164= | Silent (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- UHRF2 | c.258G>A p.Q86= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- VPS13C | c.8961C>T p.I2987= (on ENST00000644861 / NM_020821.3; = p.I2944= on NM_017684.5) | Silent (SNP) | VAF 32/207 reads (15%) | catalogued as rs757708205; called by muse, mutect2, varscan2
- ZNF497 | c.492C>T p.C164= | Silent (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- AATF | c.1548-38T>A | Intron (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- ABLIM2 | c.1516+224G>A | Intron (SNP) | VAF 77/182 reads (42%) | called by muse, mutect2, varscan2
- ALKBH5 | c.*445C>T | 3'UTR (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2
- AP001830.2 | n.460A>C | RNA (SNP) | VAF 71/300 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF38 | c.*2884T>C | 3'UTR (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- ARRDC4 | c.*357A>G | 3'UTR (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- ATG2B | c.*543C>T | 3'UTR (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.811+71T>C | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- BAIAP2 | c.1501-105A>C | Intron (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021359 T>G | 5'Flank (SNP) | VAF 22/94 reads (23%) | called by muse, varscan2
- BCL7A | chr12:122021402 C>T | 5'Flank (SNP) | VAF 22/92 reads (24%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, varscan2
- BCL7C | c.-54C>T | 5'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as rs1231410448; called by muse, mutect2, varscan2
- C20orf181 | n.385C>T | RNA (SNP) | VAF 29/64 reads (45%) | catalogued as rs1435869788; called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949950 T>C | 3'Flank (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- CASD1 | c.*224A>C | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- CBLN3 | c.*673G>A | 3'UTR (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- CCNI | c.-103C>T | 5'UTR (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- CERS3 | c.*2194G>A | 3'UTR (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- CFAP300 | c.*303T>A | 3'UTR (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- CREB5 | c.*3086T>C | 3'UTR (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- CXCL5 | c.*1293G>A | 3'UTR (SNP) | VAF 28/90 reads (31%) | catalogued as rs201431501; called by muse, mutect2, varscan2
- DAPK2 | c.858+1647G>A | Intron (SNP) | VAF 42/247 reads (17%) | called by muse, mutect2, varscan2
- DENND4A | chr15:65660240 G>A | 3'Flank (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- DGKA | c.1652+115C>G | Intron (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- DSG4 | c.2138-74C>T | Intron (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- DZIP3 | c.*6+50C>A | Intron (SNP) | VAF 34/108 reads (31%) | called by muse, mutect2, varscan2
- EIF1AY | c.256-160T>G | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- EPHA10 | c.*71C>T | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- EPHA5 | c.*3456T>G | 3'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- EPHA5 | c.*1199C>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- ETV1 | chr7:13891696 T>G | 3'Flank (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- FKTN | c.*1946C>G | 3'UTR (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- GLMN | c.-47G>A | 5'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- GNB1L | c.*1187C>T | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- GPAT3 | c.1126-75T>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- GPC1 | c.167-9370T>C | Intron (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- GRM7 | c.*718T>C | 3'UTR (SNP) | VAF 39/147 reads (27%) | catalogued as rs1018616115; called by muse, mutect2, varscan2
- GSTM3 | c.*2559A>C | 3'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- HDAC6 | chrX:48801921 G>A | 5'Flank (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- HLCS | c.-98C>T | 5'UTR (SNP) | VAF 64/264 reads (24%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.*938T>G | 3'UTR (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- HOOK1 | c.*1443A>G | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- HOXC5 | c.-221T>C | 5'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- IFT122 | c.2988-449G>A | Intron (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- INSYN1 | c.-61C>T | 5'UTR (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- ISCU | c.*119T>A | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2
- KCNIP3 | c.*1650G>A | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- KCNMB4 | c.465-7707C>T | Intron (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- KIF3B | c.*3099C>T | 3'UTR (SNP) | VAF 10/167 reads (6%) | catalogued as rs1055731506; called by muse, mutect2
- LATS1 | chr6:149659195 C>T | 3'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as rs747904660; called by muse, mutect2, varscan2
- LHFPL6 | c.*340T>G | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- LRAT | c.*1837G>A | 3'UTR (SNP) | VAF 38/91 reads (42%) | catalogued as rs564373777; called by muse, mutect2, varscan2
- LRP11 | c.*201G>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- LUZP2 | c.*1025G>A | 3'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- LYRM7 | c.*111T>C | 3'UTR (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- MDM4 | c.*5852C>T | 3'UTR (SNP) | VAF 8/31 reads (26%) | called by mutect2, varscan2
- MIR5195 | chr14:106851227 G>A | 5'Flank (SNP) | VAF 54/131 reads (41%) | catalogued as rs760626046; called by muse, mutect2, varscan2
- MMRN1 | c.*86G>T | 3'UTR (SNP) | VAF 13/38 reads (34%) | catalogued as rs1418632469; called by muse, mutect2, varscan2
- MTR | c.*3114C>T | 3'UTR (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- NACC2 | c.*4430dup | 3'UTR (INS) | VAF 55/235 reads (23%) | catalogued as rs371539423; called by mutect2, varscan2
- NFIA | c.*6656T>G | 3'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+4830T>C | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- NTPCR | c.*298A>T | 3'UTR (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- PARP11 | c.*597C>T | 3'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*179C>T | 3'UTR (SNP) | VAF 72/190 reads (38%) | called by muse, mutect2, varscan2
- POLN | c.1731+180C>A | Intron (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- PRSS23 | c.207-12140del | Intron (DEL) | VAF 19/158 reads (12%) | called by mutect2, pindel, varscan2
- PTBP3 | c.*274A>G | 3'UTR (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- RERGL | c.-14G>A | 5'UTR (SNP) | VAF 47/119 reads (39%) | called by muse, mutect2, varscan2
- RIMBP2 | c.*1110C>T | 3'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- ROM1 | chr11:62611745 G>A | 5'Flank (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2
- SCN2B | c.*1638C>T | 3'UTR (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- SECISBP2L | c.203+29dup | Intron (INS) | VAF 22/61 reads (36%) | catalogued as rs772353690; called by mutect2, pindel, varscan2
- SEMA5A | c.*3434A>T | 3'UTR (SNP) | VAF 65/212 reads (31%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.*2067del | 3'UTR (DEL) | VAF 41/131 reads (31%) | called by mutect2, varscan2
- SH3BP5L | c.*1098C>T | 3'UTR (SNP) | VAF 22/136 reads (16%) | catalogued as rs761846516; called by muse, mutect2, varscan2
- SIAH2 | c.*637T>C | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- SLC44A5 | chr1:75203778 T>C | 3'Flank (SNP) | VAF 78/213 reads (37%) | called by muse, mutect2, varscan2
- SPATA31D4 | c.*130C>G | 3'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2
- ST20-MTHFS | c.-12+91C>G | Intron (SNP) | VAF 16/121 reads (13%) | catalogued as rs1414935448; called by muse, mutect2, varscan2
- ST8SIA1 | c.*166G>A | 3'UTR (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.*2060A>T | 3'UTR (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- TAFA5 | c.113-70158G>A | Intron (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- TEDC2 | chr16:2458870 T>C | 5'Flank (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- TFCP2 | c.*1540G>A | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.-435G>T | 5'UTR (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- TNKS2 | c.*1947T>A | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- TP53INP2 | c.*2487A>T | 3'UTR (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- TRMT1L | c.-101A>G | 5'UTR (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- UHMK1 | c.*4181G>T | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- UROC1 | c.*878C>G | 3'UTR (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- VPS41 | c.*1195C>T | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-897+3511G>A | Intron (SNP) | VAF 63/176 reads (36%) | catalogued as rs370213262; called by muse, mutect2, varscan2
- ZFP42 | c.*205G>T | 3'UTR (SNP) | VAF 28/62 reads (45%) | catalogued as rs1241742331, COSV100478849; called by muse, mutect2, varscan2
- ZNF254 | c.157+39A>G | Intron (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- ZNF644 | c.*1353C>T | 3'UTR (SNP) | VAF 25/76 reads (33%) | catalogued as rs1328586818; called by muse, mutect2, varscan2
